Gene-level copy-number profile of tumor specimen TCGA-12-1600-01A from TCGA case TCGA-12-1600, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 86.0 years (31,419 days).
Specimen TCGA-12-1600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ae80de24-cb66-4c58-a4ed-9f3ce857ead6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1600-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70e398bd-20ec-4b85-8149-d2b93b2fec3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,764; copy number 2: 43,604; copy number 3: 7,245; copy number 6: 145; copy number 7: 49; copy number 28: 3; copy number 29: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-1600-01A-01D-0591-01): tumor purity 0.9, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 206 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,621,025–55,260,256, 12 genes, copy number 28–29: RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr14:20,768,404–21,104,722, 27 genes, copy number 7: EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1, RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219, TMEM253.
- chr14:22,519,969–24,052,555, 105 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr14:26,443,090–26,598,033, 1 gene, copy number 7 (within-gene range 2–7): NOVA1.
- chr14:68,787,660–69,153,150, 11 genes, copy number 6: ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA.
- chr14:73,040,619–73,223,691, 6 genes, copy number 6: RN7SL586P, AL442663.3, RBM25, AL442663.2, PSEN1, AC004858.1.
- chr14:73,242,651–73,246,880, 2 genes, copy number 6: AC004846.1, RNU6-419P.
- chr14:73,851,971–73,932,278, 1 gene, copy number 7 (within-gene range 2–7): AC005520.1.
- chr14:73,886,617–74,303,055, 16 genes, copy number 7 (within-gene range 2–7): ZNF410, AC005480.1, AC005520.3, Y_RNA, FAM161B, COQ6, ENTPD5, AC005480.2, BBOF1, ALDH6A1, LIN52, RN7SL530P, AC006349.1, VSX2, ABCD4, AC005519.1.
- chr14:74,305,425–74,306,527, 1 gene, copy number 7: SUB1P2.
- chr14:104,474,678–105,010,482, 24 genes, copy number 6–7 (within-gene range 2–7): TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1.

Autosomal genes at a single copy (total copy number 1): 6,384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
